Somatic mutation profile of tumor specimen TCGA-MA-AA3Z-01A (aliquot TCGA-MA-AA3Z-01A-11D-A387-09) from TCGA case TCGA-MA-AA3Z, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: GX; Age at diagnosis: 43.2 years (15,762 days).
Specimen TCGA-MA-AA3Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 94d91ec3-61bf-4286-ac2c-b9b4ad60ba72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MA-AA3Z-10A (Blood Derived Normal), aliquot TCGA-MA-AA3Z-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e25e2032-8c9b-4144-acd4-7c3265a91954

The open-access MAF lists 202 somatic variants for this specimen: 138 protein-altering or splice-affecting, 58 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 58, Nonsense Mutation 10, Intron 3, RNA 2, 3'UTR 1, Frame Shift Ins 1, Splice Site 1, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 83/221 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB6 | c.1002G>A p.W334* | Nonsense Mutation (SNP) | VAF 8/24 reads (33%) | catalogued as COSV99521397; called by muse, mutect2, varscan2
- ABCB6 | c.661G>C p.E221Q | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.094); catalogued as COSV99521399; called by muse, mutect2, varscan2
- AK9 | c.3202G>C p.E1068Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV100392932; called by muse, mutect2, varscan2
- AKR1B10 | c.914C>G p.S305C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as rs781593224, COSV62054973; called by muse, mutect2, varscan2
- ANAPC10 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.563); catalogued as rs1327991661, COSV100518545; called by muse, mutect2, varscan2
- ANAPC13 | c.165G>A p.M55I | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61566308; called by muse, mutect2, varscan2
- ANK3 | c.12474G>C p.L4158F (on ENST00000280772 / NM_001320874.2; = p.L679F on NM_001149.3) | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99777740; called by muse, mutect2, varscan2
- ANO5 | c.2362G>A p.D788N | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.524); catalogued as COSV100201285; called by muse, mutect2, varscan2
- ARFGAP1 | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.325); catalogued as rs753214798, COSV100796603; called by muse, mutect2, varscan2
- ATP13A5 | c.865C>T p.L289F | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100664619; called by muse, mutect2, varscan2
- BEND4 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 17/24 reads (71%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.021); catalogued as COSV101549698, COSV72469155; called by muse, mutect2, varscan2
- BMPER | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99778625; called by muse, mutect2, varscan2
- BMPR1B | c.1464G>T p.K488N | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99215242; called by muse, mutect2, varscan2
- BMS1 | c.2332G>A p.E778K | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100996401; called by muse, mutect2, varscan2
- CABP4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs765171666, COSV56886126, COSV56886438; called by muse, mutect2, varscan2
- CACNA1F | c.3351C>A p.F1117L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV100544248; called by muse, mutect2, varscan2
- CDH12 | c.2125G>C p.D709H | Missense Mutation (SNP) | VAF 33/218 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV101200705; called by muse, mutect2, varscan2
- CDH5 | c.1290G>C p.E430D | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as COSV100438919; called by muse, mutect2, varscan2
- CENPF | c.6049C>T p.Q2017* | Nonsense Mutation (SNP) | VAF 12/66 reads (18%) | catalogued as COSV100871428; called by muse, mutect2
- CENPF | c.6245C>T p.S2082L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV100871429; called by muse, mutect2, varscan2
- CEP250 | c.5860C>T p.H1954Y | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.201); catalogued as COSV100698693; called by muse, mutect2
- CFAP47 | c.486G>C p.E162D | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV99934115, COSV99935829; called by muse, mutect2
- CHD6 | c.263G>A p.G88E | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.255); catalogued as rs146163707; called by muse, mutect2, varscan2
- CHST15 | c.293T>G p.L98R | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100654867; called by muse, mutect2, varscan2
- CLEC16A | c.2042G>A p.R681Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs764755955, COSV68502290; called by muse, mutect2
- CLHC1 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV101284814; called by muse, mutect2, varscan2
- COL8A1 | c.1777G>C p.D593H | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as COSV53732533; called by muse, mutect2, varscan2
- CSPG4 | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284915934, COSV57894958; called by muse, mutect2, varscan2
- CSPG5 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53130294; called by muse, mutect2, varscan2
- CTAGE6 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 36/472 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV101417796; called by muse, mutect2
- CUZD1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs267602403, COSV100158532; called by muse, mutect2, varscan2
- CUZD1 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV100158534; called by muse, mutect2, varscan2
- DAAM1 | c.1582C>T p.P528S | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100658053; called by muse, mutect2, varscan2
- DIAPH2 | c.2822A>G p.D941G | Missense Mutation (SNP) | VAF 13/122 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1351220944, COSV100230152, COSV61269113; called by mutect2, varscan2
- DNAH1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.005); catalogued as COSV101324373; called by muse, mutect2, varscan2
- DNAH10 | c.268C>T p.Q90* (on ENST00000409039; = p.Q29* on NM_207437.3) | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as COSV101291877, COSV68998753; called by muse, mutect2, varscan2
- DOCK6 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99370836; called by muse, mutect2, varscan2
- DOCK7 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV99222319; called by muse, mutect2
- DOCK9 | c.2443C>T p.H815Y (on ENST00000376460 / NM_001366676.2; = p.H816Y on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.063); catalogued as COSV100237496; called by muse, mutect2, varscan2
- DOP1B | c.4393C>A p.Q1465K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.94); PolyPhen benign (0.047); catalogued as COSV101214901; called by muse, mutect2, varscan2
- DPYD | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV100928369; called by muse, mutect2, varscan2
- EIF4G1 | c.1316C>T p.S439F (on ENST00000346169 / NM_198241.3; = p.S243F on NM_004953.5) | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV100071344; called by muse, mutect2
- EIF5 | c.89A>G p.N30S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99384628; called by muse, mutect2, varscan2
- FAM111A | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.118); catalogued as COSV100659311; called by muse, mutect2, varscan2
- FAM47B | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100263952; called by muse, mutect2, varscan2
- FBXW7 | c.1193C>T p.S398F (on ENST00000281708 / NM_001349798.2; = p.S318F on NM_018315.5) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55915633, COSV55933240; called by muse, mutect2, varscan2
- FRMPD4 | c.2752G>C p.E918Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66217812; called by muse, mutect2, varscan2
- FSHR | c.47C>G p.S16* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100436356; called by muse, mutect2, varscan2
- FUT2 | c.155C>A p.S52* | Nonsense Mutation (SNP) | VAF 28/67 reads (42%) | catalogued as COSV101217977, COSV67179276; called by muse, mutect2, varscan2
- GANAB | c.2563C>G p.Q855E | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV99641679; called by muse, mutect2, varscan2
- GBP7 | c.794C>G p.S265* | Nonsense Mutation (SNP) | VAF 53/156 reads (34%) | catalogued as COSV99642739; called by muse, mutect2, varscan2
- GP5 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100540514; called by muse, mutect2, varscan2
- H2BU1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.02); catalogued as COSV100797224; called by muse, mutect2, varscan2
- H4-16 | c.190G>C p.E64Q | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV100797598, COSV100797641; called by muse, mutect2, varscan2
- HCCS | c.523G>C p.E175Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as COSV100335596; called by muse, mutect2, varscan2
- HCRTR2 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1455076536, COSV100904074, COSV63798896; called by muse, mutect2, varscan2
- HDAC2 | c.691G>A p.D231N | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100892525; called by muse, mutect2, varscan2
- HDLBP | c.793C>T p.R265W | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs756722367, COSV100189685; called by muse, mutect2, varscan2
- IQCN | c.3293C>T p.S1098F | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.95); catalogued as COSV100828142, COSV100828456; called by muse, mutect2, varscan2
- ISLR2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.73); catalogued as rs775666741, COSV100679327; called by muse, mutect2, varscan2
- ITGB1 | c.1480G>C p.G494R | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100171161; called by muse, mutect2, varscan2
- KIF17 | c.460G>A p.D154N | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV56117332, COSV99928328; called by muse, mutect2, varscan2
- KIF3C | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99266936; called by muse, mutect2, varscan2
- KLHL24 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 47/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261493748, COSV54428115; called by muse, mutect2, varscan2
- L1TD1 | c.1113G>A p.M371I | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100776520; called by muse, mutect2, varscan2
- LAMA1 | c.6680C>A p.P2227Q | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.805); catalogued as COSV67533896; called by muse, mutect2, varscan2
- LRRC37A2 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 47/320 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.248); catalogued as rs1436136161, COSV100238576; called by muse, mutect2, varscan2
- LTV1 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.217); catalogued as COSV99394086; called by muse, mutect2
- MAN2B1 | c.2887G>A p.E963K | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs757072948, CD124187, COSV55470803; called by muse, mutect2, varscan2
- MMP3 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as COSV100242614; called by muse, mutect2, varscan2
- MTMR4 | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.013); catalogued as COSV100050675; called by muse, mutect2, varscan2
- MTMR4 | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs775955438, COSV100050677; called by muse, mutect2, varscan2
- MYH10 | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV99343809; called by muse, mutect2, varscan2
- MYH8 | c.5277G>C p.K1759N | Missense Mutation (SNP) | VAF 6/130 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101238076, COSV67972497; called by muse, mutect2
- MYO5B | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 40/100 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.61); catalogued as COSV99543256; called by muse, mutect2, varscan2
- MYOM1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.08); catalogued as COSV99864912; called by muse, mutect2, varscan2
- NAT2 | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV99673869; called by muse, mutect2
- NDUFB7 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1284343720, COSV99294978; called by muse, mutect2, varscan2
- NLGN3 | c.1282G>C p.D428H (on ENST00000358741 / NM_181303.2; = p.D408H on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV100704503; called by muse, mutect2, varscan2
- NT5DC2 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.227); catalogued as COSV100194436; called by muse, varscan2
- NUAK2 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100903949; called by muse, mutect2, varscan2
- OR4F15 | c.117G>A p.M39I | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.005); catalogued as COSV100173803, COSV104407704; called by muse, mutect2, varscan2
- PCDHA11 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1187011496, COSV56481398; called by muse, mutect2, varscan2
- PCNX4 | c.2016T>A p.C672* (on ENST00000406854 / NM_001330177.2; = p.C438* on NM_022495.5) | Nonsense Mutation (SNP) | VAF 52/135 reads (39%) | catalogued as COSV100469690; called by muse, mutect2, varscan2
- PLCH2 | c.1477G>A p.D493N | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as rs1189455018, COSV99615319; called by muse, mutect2, varscan2
- PLEKHA6 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99691384; called by muse, mutect2, varscan2
- PLIN2 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99438638; called by muse, mutect2, varscan2
- PLPP3 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100984502; called by muse, mutect2, varscan2
- POTEE | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.164); catalogued as COSV100386566; called by muse, mutect2, varscan2
- PRAG1 | c.3958G>A p.E1320K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs768786380, COSV100421746; called by muse, mutect2, varscan2
- PRDM4 | c.2320G>C p.D774H | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.043); catalogued as COSV99946302; called by muse, mutect2, varscan2
- PRRC2C | c.7799C>G p.S2600C (on ENST00000367742; = p.S2598C on NM_015172.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100144521; called by mutect2, varscan2
- RALBP1 | c.742G>C p.D248H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99191864; called by muse, mutect2, varscan2
- RBMX | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.441); catalogued as COSV100284472; called by muse, varscan2
- RNASE1 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); catalogued as COSV100564458; called by muse, mutect2, varscan2
- RNF111 | c.2551-1G>T p.X851_splice | Splice Site (SNP) | VAF 17/71 reads (24%) | catalogued as COSV100788620; called by muse, mutect2, varscan2
- RNF19A | c.1334A>T p.Y445F | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100347294; called by muse, mutect2, varscan2
- RORB | c.958C>T p.R320C (on ENST00000396204 / NM_001365023.1; = p.R309C on NM_006914.4) | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65335638; called by muse, mutect2, varscan2
- RPL10 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 46/187 reads (25%) | catalogued as COSV99185796; called by muse, mutect2, varscan2
- SCN7A | c.2581G>A p.G861S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.84); PolyPhen benign (0.006); catalogued as COSV101313045, COSV69270309; called by muse, mutect2, varscan2
- SCRN1 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.373); catalogued as COSV99620643; called by muse, mutect2, varscan2
- SFXN3 | c.896G>A p.S299N | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs1350301254, COSV99827332; called by muse, mutect2, varscan2
- SHPK | c.1006C>A p.Q336K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.037); catalogued as COSV99843585; called by muse, mutect2, varscan2
- SLC12A6 | c.2167G>A p.E723K (on ENST00000354181 / NM_001365088.1; = p.E672K on NM_005135.2) | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV51625782, COSV99270725; called by muse, mutect2, varscan2
- SLC25A18 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.172); catalogued as rs377499475; called by muse, mutect2, varscan2
- SLC26A6 | c.1939C>G p.Q647E | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as rs551934028, COSV100257933; called by muse, mutect2, varscan2
- SLC2A10 | c.1420G>A p.G474S | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756530921, COSV100826325; called by muse, mutect2, varscan2
- SLC45A2 | c.520C>G p.Q174E | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1192657734, COSV99672215; called by muse, mutect2, varscan2
- SLC52A3 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267606686, CM101476, COSV99447500; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG17 | c.5761C>T p.Q1921* | Nonsense Mutation (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100307531; called by muse, mutect2
- SPATA1 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV55364400; called by muse, mutect2, varscan2
- SPECC1L | c.2827G>A p.V943M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100061544; called by muse, mutect2, varscan2
- SYTL3 | c.1505C>T p.S502L (on ENST00000611299 / NM_001242394.1; = p.S434L on NM_001009991.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.248); catalogued as COSV99791400; called by muse, mutect2
- TBX3 | c.1261C>T p.R421W (on ENST00000257566 / NM_016569.4; = p.R401W on NM_005996.4) | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs912240752, COSV57469992; called by muse, mutect2
- TCFL5 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99415448; called by muse, mutect2, varscan2
- TERT | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as rs1474097655, COSV99715752; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TERT | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99715755; called by muse, mutect2, varscan2
- UBQLN4 | c.1269G>A p.M423I | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV100849268; called by muse, mutect2, varscan2
- UBR4 | c.12737C>T p.S4246F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV100919993; called by muse, mutect2, varscan2
- USF3 | c.3107C>G p.P1036R | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.161); catalogued as COSV100324620; called by muse, mutect2, varscan2
- USP12 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV99997350; called by muse, mutect2, varscan2
- USP15 | c.2917G>A p.E973K (on ENST00000280377 / NM_001351159.2; = p.E944K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs768980880, COSV99738285; called by muse, mutect2, varscan2
- USP9X | c.4282G>A p.E1428K | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100198321; called by muse, mutect2, varscan2
- XIRP2 | c.9912T>A p.N3304K (on ENST00000628543; = p.N3479K on NM_152381.6) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1478158538, COSV54682622; called by muse, mutect2, varscan2
- XRN2 | c.2285A>T p.E762V | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV101017880; called by muse, mutect2
- YKT6 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as COSV99790446; called by muse, mutect2, varscan2
- ZBTB10 | c.2149C>G p.L717V (on ENST00000430430; = p.L693V on NM_023929.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1213639981, COSV100990028; called by muse, mutect2, varscan2
- ZBTB26 | c.505T>C p.S169P | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV101020993; called by muse, mutect2, varscan2
- ZBTB7A | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 81/220 reads (37%) | catalogued as COSV100475276; called by muse, mutect2, varscan2
- ZFHX4 | c.5301G>A p.M1767I | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99254713, COSV99257128; called by muse, mutect2, varscan2
- ZNF436 | c.178G>A p.E60K | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.055); catalogued as rs1439367323, COSV100010795; called by muse, mutect2, varscan2
- ZNF750 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV53961778, COSV99489481; called by muse, mutect2, varscan2
- ZSCAN20 | c.2912G>A p.R971H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs759274340, COSV100792460; called by muse, mutect2, varscan2
- ASXL1 | c.1613del p.K538Rfs*165 | Frame Shift Del (DEL) | VAF 27/90 reads (30%) | called by mutect2, pindel, varscan2
- GDF2 | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- VAV2 | c.496_508dup p.D170Gfs*21 (on ENST00000371850 / NM_001134398.2; = p.D170Gfs*25 on NM_003371.4) | Frame Shift Ins (INS) | VAF 8/34 reads (24%) | called by mutect2, varscan2
- ZNF540 | c.1756_1758del p.K586del | In Frame Del (DEL) | VAF 18/67 reads (27%) | called by mutect2, pindel, varscan2
- ALG12 | c.222C>T p.I74= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs371496005; called by muse, mutect2, varscan2
- ATF5 | c.750G>A p.L250= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100351731; called by muse, mutect2
- CASR | c.600C>T p.I200= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs1166789936, COSV56141435; called by muse, mutect2, varscan2
- CCDC60 | c.984G>A p.L328= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as rs1480634987, COSV100554464; called by muse, mutect2, varscan2
- CDC42BPB | c.4518G>A p.L1506= | Silent (SNP) | VAF 21/53 reads (40%) | catalogued as COSV100775077; called by muse, mutect2, varscan2
- CEP126 | c.3060G>A p.L1020= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV54826856, COSV99680449; called by muse, mutect2, varscan2
- CFHR4 | c.1305T>A p.G435= (on ENST00000367416 / NM_001201551.2; = p.G189= on NM_006684.5) | Silent (SNP) | VAF 38/105 reads (36%) | catalogued as COSV52235784, COSV99259226; called by muse, mutect2, varscan2
- CLMN | c.2364G>A p.E788= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs965686686, COSV100111901; called by muse, varscan2
- CNTRL | c.594C>G p.L198= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV99440800; called by muse, mutect2, varscan2
- CR2 | c.171C>T p.L57= | Silent (SNP) | VAF 9/115 reads (8%) | catalogued as rs1286391697, COSV100889506; called by muse, mutect2
- CXXC1 | c.963G>A p.R321= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs762206193, COSV99495224; called by muse, mutect2, varscan2
- CYP3A4 | c.1604G>A p.*535= (on ENST00000336411; = p.*504= on NM_017460.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 31/89 reads (35%) | catalogued as rs772460209, COSV100315358; called by muse, mutect2, varscan2
- DACH2 | c.1674G>A p.R558= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100912343, COSV64165093; called by muse, mutect2, varscan2
- DCAF15 | c.312C>T p.F104= | Silent (SNP) | VAF 29/87 reads (33%) | catalogued as COSV99586670; called by muse, mutect2, varscan2
- DENND2A | c.1482G>C p.R494= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV99325406; called by muse, mutect2, varscan2
- DNAH2 | c.5643C>T p.A1881= | Silent (SNP) | VAF 32/75 reads (43%) | catalogued as rs144218986; called by muse, mutect2, varscan2
- EPHB4 | c.339C>T p.V113= | Silent (SNP) | VAF 12/83 reads (14%) | catalogued as rs1365415926, COSV100639379; called by muse, mutect2, varscan2
- ERAL1 | c.96T>C p.P32= | Silent (SNP) | VAF 5/55 reads (9%) | catalogued as COSV99650184; called by muse, mutect2
- ERCC2 | c.1332C>T p.I444= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV101228675; called by muse, mutect2
- EXOSC10 | c.891C>T p.L297= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs780071646, COSV58666660; called by muse, mutect2, varscan2
- FAM214A | c.2358G>A p.L786= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as rs747424840, COSV99957486; called by muse, mutect2, varscan2
- FBH1 | c.1482C>T p.I494= (on ENST00000362091 / NM_178150.3; = p.I545= on NM_032807.4) | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as rs774671116, COSV100758562; called by muse, mutect2, varscan2
- HOXC6 | c.429C>T p.R143= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99678896; called by muse, mutect2, varscan2
- IDO2 | c.33A>T p.A11= (on ENST00000389060; = p.A24= on NM_194294.2) | Silent (SNP) | VAF 47/123 reads (38%) | catalogued as COSV100584458; called by muse, mutect2, varscan2
- IGDCC4 | c.2910C>A p.L970= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100732616; called by muse, mutect2
- LAMC1 | c.891G>A p.K297= | Silent (SNP) | VAF 10/108 reads (9%) | catalogued as COSV99278733; called by muse, mutect2, varscan2
- LGR6 | c.510C>T p.D170= (on ENST00000367278 / NM_001017403.1; = p.D118= on NM_021636.3) | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as rs373499034; called by muse, mutect2, varscan2
- MAP4 | c.2679C>T p.P893= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as COSV99274501; called by muse, mutect2, varscan2
- MBLAC1 | c.351G>A p.S117= | Silent (SNP) | VAF 40/103 reads (39%) | catalogued as rs367768137; called by muse, mutect2, varscan2
- MOGS | c.462C>T p.L154= | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV99280785; called by muse, mutect2, varscan2
- MON2 | c.5049C>T p.I1683= | Silent (SNP) | VAF 49/124 reads (40%) | catalogued as COSV99741346; called by muse, mutect2, varscan2
- MUC16 | c.43464C>T p.N14488= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs556135322, COSV101109479; called by muse, mutect2, varscan2
- MYH3 | c.1743C>T p.I581= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV99877582; called by muse, mutect2, varscan2
- NCOA6 | c.2127G>A p.Q709= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as COSV100749877, COSV62865768; called by muse, mutect2, varscan2
- NPEPL1 | c.1434C>T p.F478= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs761006655, COSV61937956; called by muse, mutect2, varscan2
- OR6C68 | c.765C>T p.F255= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV101110001; called by muse, mutect2, varscan2
- PARD6G | c.846G>A p.P282= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs761643537, COSV100783298; called by muse, varscan2
- POMT2 | c.765G>A p.L255= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99836115; called by muse, mutect2, varscan2
- RABGAP1 | c.2232C>T p.I744= | Silent (SNP) | VAF 61/140 reads (44%) | catalogued as COSV101016587; called by muse, mutect2, varscan2
- RPS6KA1 | c.1908C>T p.L636= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as rs1360178040, COSV100942855; called by muse, mutect2
- SCN2A | c.4395G>A p.L1465= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV99329709, COSV99330493; called by muse, mutect2, varscan2
- SHISAL2A | c.93C>G p.V31= | Silent (SNP) | VAF 24/37 reads (65%) | catalogued as COSV101284204; called by muse, mutect2, varscan2
- SLC16A13 | c.489C>T p.L163= | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV100338533; called by muse, mutect2, varscan2
- SLC47A2 | c.1401C>T p.I467= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99449500; called by muse, mutect2, varscan2
- SLC4A4 | c.1242G>A p.Q414= (on ENST00000264485 / NM_001098484.3; = p.Q370= on NM_003759.4) | Silent (SNP) | VAF 21/115 reads (18%) | catalogued as COSV99138800; called by muse, mutect2, varscan2
- SLC8A3 | c.1569C>T p.I523= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV100775817; called by muse, mutect2, varscan2
- SLC9A2 | c.1125C>T p.F375= | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV52129344; called by muse, mutect2, varscan2
- SNAPC4 | c.2377C>T p.L793= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as rs1460928196, COSV100046684; called by muse, mutect2, varscan2
- SPOCD1 | c.1873C>A p.R625= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV99929342; called by muse, mutect2, varscan2
- STOML3 | c.351A>G p.G117= | Silent (SNP) | VAF 22/60 reads (37%) | catalogued as COSV101105123; called by muse, mutect2, varscan2
- SYDE1 | c.2139C>G p.L713= | Silent (SNP) | VAF 19/32 reads (59%) | catalogued as rs774699974, COSV99654510; called by muse, mutect2, varscan2
- TBC1D15 | c.1878G>A p.E626= | Silent (SNP) | VAF 28/106 reads (26%) | catalogued as COSV100041273; called by muse, mutect2, varscan2
- TEKT3 | c.1365C>T p.L455= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs779576381, COSV100106695; called by muse, mutect2, varscan2
- TSHZ2 | c.2448C>A p.V816= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs552622643, COSV100295175, COSV100295449; called by muse, mutect2, varscan2
- ULK4 | c.3711C>G p.L1237= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as rs1221812410, COSV100089623; called by muse, mutect2, varscan2
- ZNF416 | c.603C>T p.I201= | Silent (SNP) | VAF 15/104 reads (14%) | catalogued as COSV99543653; called by muse, mutect2, varscan2
- ZNF750 | c.441C>A p.L147= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99489483; called by muse, mutect2, varscan2
- ZSCAN25 | c.1077G>A p.R359= | Silent (SNP) | VAF 4/59 reads (7%) | catalogued as COSV53552682; called by muse, mutect2
- AGAP7P | n.1187C>G | RNA (SNP) | VAF 94/279 reads (34%) | called by muse, mutect2, varscan2
- ATAD3B | c.*642G>C | 3'UTR (SNP) | VAF 11/111 reads (10%) | catalogued as COSV100426256; called by muse, mutect2
- ATP2B1 | c.3351+397G>A | Intron (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53806772, COSV99665068; called by muse, mutect2, varscan2
- CRYM-AS1 | n.504G>C | RNA (SNP) | VAF 15/64 reads (23%) | called by muse, mutect2, varscan2
- MAP3K20 | c.987+4233G>T | Intron (SNP) | VAF 12/57 reads (21%) | catalogued as COSV100168658; called by muse, mutect2, varscan2
- MASP1 | c.1303+5667G>A | Intron (SNP) | VAF 15/78 reads (19%) | catalogued as COSV56220800, COSV99961695; called by muse, mutect2, varscan2
